Somatic mutation profile of tumor specimen MMRF_1391_2_BM_CD138pos (aliquot MMRF_1391_2_BM_CD138pos_T1_KBS5U_L05832) from MMRF case MMRF_1391, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.4 years (23,871 days).
Specimen MMRF_1391_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4e9b84a-eb4e-4837-a024-434d0869e50a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1391_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1391_1_PB_Whole_C2_KAS5U_L00677; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98200ee7-d24c-4d8a-9aa0-5ffe08858f7b

The open-access MAF lists 4 somatic variants for this specimen: 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A20 | c.1314C>T p.C438= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TLE3 | c.-1019_-1016delinsG | 5'UTR (DEL) | VAF 6/64 reads (9%) | catalogued as COSV58168191; called by pindel, varscan2*
- UBL3 | c.-1050C>T | 5'UTR (SNP) | VAF 4/85 reads (5%) | catalogued as rs1214947372; called by muse, mutect2
- Z98752.3 | c.201+9828G>A | Intron (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
